Somatic mutation profile of tumor specimen TCGA-FD-A5BT-01A (aliquot TCGA-FD-A5BT-01A-11D-A26M-08) from TCGA case TCGA-FD-A5BT, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 84.0 years (30,686 days).
Specimen TCGA-FD-A5BT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 886453d4-2d61-4288-ad74-65f1b3c72103.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A5BT-10A (Blood Derived Normal), aliquot TCGA-FD-A5BT-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b838a8d-21b5-4e26-9ff8-8911126dd7d7

The open-access MAF lists 147 somatic variants for this specimen: 102 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 41, Nonsense Mutation 7, 5'Flank 2, Splice Site 1, RNA 1, Intron 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC109583.1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs767703397, COSV58406729; called by muse, mutect2, varscan2
- ACVR1 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55122136; called by muse, mutect2
- ADCY10 | c.272G>C p.G91A | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63245364; called by muse, mutect2
- ADGRL4 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs368339256; called by muse, mutect2
- ADIPOQ | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs770133299, COSV57858411; called by muse, mutect2, varscan2
- AGMO | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61123799, COSV61125083; called by muse, mutect2
- AKAP9 | c.10505G>C p.R3502T (on ENST00000359028; = p.R3478T on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV62358888; called by muse, varscan2
- AKR1E2 | c.543G>C p.L181F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53629547, COSV53632070; called by muse, mutect2, varscan2
- ANP32E | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV58482142, COSV58483544; called by muse, mutect2, varscan2
- AOPEP | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369261332; called by muse, mutect2, varscan2
- APH1A | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | catalogued as COSV99354590; called by muse, mutect2
- APMAP | c.1044C>G p.L348= | Splice Region (SNP) | VAF 14/76 reads (18%) | catalogued as rs754433059, COSV54177231; called by muse, mutect2, varscan2
- ARNT | c.1166A>G p.Q389R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV62232481; called by muse, mutect2
- BBC3 | c.607G>C p.E203Q (on ENST00000449228 / NM_001127240.3; = p.W168C on NM_014417.5) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100340804, COSV56263349; called by muse, mutect2, varscan2
- BIRC6 | c.14476G>T p.E4826* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV101429341; called by muse, mutect2, varscan2
- BLMH | c.48G>C p.Q16H | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.35); catalogued as COSV99913268; called by muse, mutect2
- C20orf194 | c.2997C>G p.I999M | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV52703642; called by muse, mutect2
- C7orf26 | c.194G>C p.R65T | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV60107140; called by muse, mutect2
- CAPZA1 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV54147466; called by muse, mutect2, varscan2
- CNOT1 | c.3734C>G p.S1245C | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV55322803; called by muse, mutect2
- COL28A1 | c.1682A>G p.N561S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.992); catalogued as COSV68085079, COSV68085081; called by muse, mutect2
- COL6A3 | c.3763A>G p.I1255V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV55112270; called by muse, mutect2, varscan2
- CSPG4 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs772408314, COSV57902197; called by mutect2, varscan2
- CWC22 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774081423, COSV55428900; called by muse, mutect2
- CYP2C8 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as rs1564743916, COSV100988044; called by muse, mutect2
- DCAF17 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59831201; called by muse, mutect2
- DCHS1 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55043536; called by muse, mutect2, varscan2
- DLX1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV100543260, COSV59395416; called by muse, mutect2
- DNAH17 | c.7277C>T p.A2426V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as COSV101103905; called by muse, mutect2
- DYDC2 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55473436; called by muse, mutect2
- EHBP1L1 | c.4378C>T p.Q1460* | Nonsense Mutation (SNP) | VAF 10/89 reads (11%) | catalogued as COSV100442408; called by muse, mutect2, varscan2
- EPHA8 | c.1753C>G p.Q585E | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV51303558; called by muse, mutect2, varscan2
- EVC | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs748785587, COSV53838626; called by muse, mutect2, varscan2
- F5 | c.6428C>G p.S2143C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63128940; called by muse, mutect2, varscan2
- FCRL6 | c.999G>T p.W333C | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV58942915; called by muse, mutect2, varscan2
- FMO3 | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV63007996; called by muse, mutect2
- GSPT2 | c.1567G>C p.D523H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61215312; called by muse, mutect2, varscan2
- GTF2H4 | c.1299C>G p.F433L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV99462271, COSV99462431; called by muse, mutect2
- GULP1 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63075595; called by muse, mutect2
- HAUS4 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.84); catalogued as COSV52828417; called by muse, mutect2
- HAX1 | c.499C>G p.H167D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV55182036; called by muse, mutect2, varscan2
- IGHV3-15 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.996); catalogued as rs1555443685; called by muse, mutect2
- IL17REL | c.292C>G p.H98D | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV58009231; called by muse, mutect2
- ITGB4 | c.1769G>A p.C590Y | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM136442, COSV52333515; called by muse, mutect2
- ITIH2 | c.402G>C p.E134D | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.97); catalogued as COSV64435432; called by muse, mutect2
- KREMEN1 | c.863C>A p.P288Q (on ENST00000407188; = p.P290Q on NM_032045.5) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59914972; called by muse, mutect2, varscan2
- LATS1 | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); catalogued as COSV53591062, COSV53600751; called by muse, mutect2
- LIG4 | c.2637A>T p.R879S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as COSV63598195; called by muse, mutect2, varscan2
- LONP2 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53526662, COSV99589473; called by muse, mutect2
- LTBP2 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs879740508, COSV56214735; called by muse, mutect2, varscan2
- MCF2L | c.640G>A p.E214K (on ENST00000375608; = p.E182K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.036); catalogued as rs759172305, COSV65054484; called by muse, mutect2, varscan2
- MS4A5 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.09); catalogued as COSV55742780; called by muse, mutect2, varscan2
- MYO3B | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.241); catalogued as COSV58719178; called by muse, mutect2, varscan2
- MYO3B | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.223); catalogued as rs1359570233, COSV58719205; called by muse, mutect2
- OLFM2 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53433769; called by muse, mutect2, varscan2
- OSR1 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); catalogued as COSV55346670; called by muse, mutect2, varscan2
- PCBP4 | c.941C>G p.S314C (on ENST00000322099 / NM_033010.2; = p.S271C on NM_020418.4) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV100437217; called by muse, mutect2
- PCDH19 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.272); catalogued as rs997198770, COSV55263780; called by muse, mutect2, varscan2
- PHLDA3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66210854; called by muse, mutect2, varscan2
- PPP1R12B | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV61124336; called by muse, mutect2, varscan2
- PSG9 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52488828; called by muse, mutect2, varscan2
- PTBP3 | c.1643C>G p.S548* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as COSV100534596; called by muse, mutect2, varscan2
- RANBP6 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1020977389, COSV52391559; called by muse, mutect2
- RHCE | c.635-2A>G p.X212_splice | Splice Site (SNP) | VAF 8/113 reads (7%) | catalogued as rs1173045230, COSV53803601; called by muse, mutect2
- RNF214 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745925375, COSV56121210; called by muse, mutect2
- ROBO2 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59942258; called by muse, mutect2
- RYR2 | c.11976T>A p.N3992K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100773379; called by muse, mutect2
- SCRIB | c.2167G>C p.E723Q | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57593940; called by muse, mutect2, varscan2
- SEC61A1 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.494); catalogued as COSV54579227; called by muse, mutect2
- SLC12A5 | c.1151C>A p.S384Y (on ENST00000454036 / NM_001134771.2; = p.S361Y on NM_020708.5) | Missense Mutation (SNP) | VAF 12/388 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV54802758; called by muse, mutect2
- SLC38A1 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.167); catalogued as COSV67065034; called by muse, mutect2
- SLTM | c.2071A>G p.I691V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as COSV51058990; called by mutect2, varscan2
- STAC3 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV60414503; called by muse, mutect2, varscan2
- STARD13 | c.494G>A p.R165Q (on ENST00000336934 / NM_001243476.3; = p.R47Q on NM_052851.3) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs757238507, COSV55228950; called by muse, mutect2, varscan2
- STARD8 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV99367821; called by mutect2, varscan2
- STT3B | c.1644G>T p.M548I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.07); catalogued as COSV55506279; called by muse, mutect2, varscan2
- SUPT6H | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.024); catalogued as COSV58931899; called by muse, mutect2
- TDRD3 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV52158007; called by muse, mutect2, varscan2
- THUMPD1 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs758767309, COSV101189722; called by muse, mutect2, varscan2
- TNS1 | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs774513166, COSV50762854; called by mutect2, varscan2
- TOGARAM1 | c.4361C>T p.S1454L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV63895444; called by muse, mutect2, varscan2
- TOX | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.052); catalogued as COSV63851030; called by muse, mutect2, varscan2
- TRIM7 | c.1527C>G p.I509M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs749963929, COSV51252338; called by mutect2, varscan2
- TWNK | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV52972467; called by muse, mutect2, varscan2
- UBR5 | c.1405C>A p.Q469K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.184); catalogued as COSV55301489; called by muse, mutect2, varscan2
- UNC79 | c.5078C>T p.S1693F (on ENST00000393151 / NM_001346218.2; = p.S1516F on NM_020818.5) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs768054531, COSV56413557; called by muse, mutect2, varscan2
- USP16 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.625); catalogued as COSV54506323, COSV99725763; called by muse, mutect2
- WDFY3 | c.9418C>T p.H3140Y | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs865844377; called by muse, mutect2
- ZFYVE28 | c.1916C>G p.S639* | Nonsense Mutation (SNP) | VAF 10/140 reads (7%) | catalogued as COSV99343880; called by muse, mutect2
- ZMYND8 | c.2273C>T p.P758L (on ENST00000311275 / NM_001363741.2; = p.P778L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as rs780491504, COSV53684289; called by muse, mutect2
- ZNF398 | c.1772A>G p.N591S (on ENST00000475153 / NM_170686.3; = p.N420S on NM_020781.4) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs116863926; called by muse, mutect2, varscan2
- ZSWIM2 | c.1749G>C p.W583C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV54580106; called by muse, mutect2, varscan2
- ACACA | c.4852G>A p.D1618N | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- EBI3 | c.637del p.E213Nfs*2 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- ELMOD3 | c.861C>G p.F287L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.107); called by muse, mutect2
- EPHA8 | c.1789C>G p.L597V | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.092); called by muse, mutect2
- FAT4 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGHV3-64 | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.409); called by muse, mutect2
- INVS | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MIA2 | c.1769C>G p.S590C | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- SMG8 | c.566G>C p.W189S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZFP37 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- ACP4 | c.1044C>G p.L348= | Silent (SNP) | VAF 88/326 reads (27%) | catalogued as COSV54516501, COSV54519369; called by muse, mutect2, varscan2
- ANKRD11 | c.1977C>T p.Y659= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as rs749201074, COSV56358844; called by muse, mutect2, varscan2
- ARAP2 | c.4578G>A p.T1526= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs778349281, COSV58290162; called by muse, mutect2
- ATG9A | c.1827G>A p.Q609= | Silent (SNP) | VAF 35/245 reads (14%) | catalogued as rs1439030890, COSV54701286, COSV99521963; called by muse, mutect2, varscan2
- ATP2B4 | c.2139G>C p.L713= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV58184498; called by muse, mutect2, varscan2
- BRD7 | c.1680G>A p.Q560= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs751773053, COSV54271315; called by muse, mutect2, varscan2
- BTBD16 | c.129G>C p.L43= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV53263999, COSV53267328; called by muse, mutect2, varscan2
- CCDC141 | c.2628G>A p.E876= | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as rs775100190, COSV55383313; called by muse, mutect2, varscan2
- CDC25C | c.597G>A p.L199= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV60398499; called by muse, mutect2, varscan2
- CDSN | c.1404T>C p.T468= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99457364; called by muse, mutect2
- CLSTN3 | c.1362C>T p.L454= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as rs201416693, COSV56934712; called by muse, mutect2
- COPS6 | c.691C>T p.L231= | Silent (SNP) | VAF 10/253 reads (4%) | catalogued as COSV57999262; called by muse, mutect2
- CTAGE1 | c.126G>C p.V42= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- DOCK8 | c.1320C>A p.A440= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV66636277; called by muse, mutect2, varscan2
- ELF1 | c.135C>G p.L45= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV53503250, COSV99523278; called by muse, mutect2, varscan2
- FA2H | c.966G>A p.S322= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs766614299, COSV54725567; called by mutect2, varscan2
- FLG | c.8604T>C p.S2868= | Silent (SNP) | VAF 40/870 reads (5%) | catalogued as COSV64250646; called by muse, mutect2
- GEMIN5 | c.810G>A p.L270= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs1176619845, COSV53562446, COSV53565326; called by muse, mutect2, varscan2
- GP5 | c.714C>T p.F238= | Silent (SNP) | VAF 33/224 reads (15%) | catalogued as COSV59878207; called by muse, mutect2, varscan2
- GTF3A | c.882C>T p.L294= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs766647703, COSV63528445; called by mutect2, varscan2
- HDAC4 | c.657C>T p.S219= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs758890066, COSV61871191; called by mutect2, varscan2
- HMBOX1 | c.219G>T p.G73= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1304532872, COSV55072520; called by muse, mutect2
- IGHG3 | c.1308C>T p.P436= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as rs945735123; called by muse, mutect2, varscan2
- MTNR1A | c.892C>T p.L298= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV56158078; called by muse, mutect2
- NOTCH3 | c.1899C>G p.V633= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as CM124698, COSV99659292; called by muse, mutect2
- OSBPL5 | c.492G>A p.Q164= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV55146199; called by muse, mutect2, varscan2
- PDE10A | c.114G>A p.Q38= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100605796; called by muse, mutect2
- POC1A | c.135C>G p.V45= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV56593791; called by muse, mutect2
- PPM1J | c.1398C>G p.V466= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV53518722, COSV53519435; called by muse, mutect2
- PSG2 | c.450C>T p.S150= | Silent (SNP) | VAF 29/186 reads (16%) | catalogued as rs773893288, COSV61546705; called by muse, mutect2, varscan2
- SEC61A1 | c.1200G>A p.V400= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as rs1559799333, COSV54579238; called by muse, mutect2, varscan2
- SLC25A23 | c.1077G>A p.L359= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99902710; called by muse, mutect2
- SPATA18 | c.15G>A p.L5= | Silent (SNP) | VAF 23/159 reads (14%) | catalogued as rs752654644, COSV54650871; called by muse, mutect2, varscan2
- THUMPD3 | c.1275T>C p.A425= | Silent (SNP) | VAF 40/269 reads (15%) | catalogued as COSV61506943; called by muse, mutect2, varscan2
- TRARG1 | c.258G>A p.A86= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs752409409, COSV61563398; called by muse, mutect2, varscan2
- TSPYL6 | c.367C>T p.L123= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- TTBK2 | c.585C>T p.I195= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV51181875; called by muse, mutect2, varscan2
- UTP14C | c.1302C>T p.L434= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV73000678, COSV73000829; called by muse, mutect2, varscan2
- WDR24 | c.2364C>T p.I788= (on ENST00000248142; = p.I658= on NM_032259.4) | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs1456318735, COSV50197045; called by muse, mutect2
- ZMYND15 | c.1281C>T p.L427= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV52645290; called by muse, mutect2
- ZSWIM4 | c.909G>T p.L303= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV54326471; called by muse, mutect2
- AP000769.3 | chr11:65504399 G>C | 5'Flank (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- FOLH1B | n.1722A>G | RNA (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- RNF213 | c.3024+75G>A | Intron (SNP) | VAF 9/74 reads (12%) | catalogued as rs1173740669, COSV60630893; called by muse, mutect2, varscan2
- Y_RNA | chr7:75515781 C>T | 5'Flank (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
